Surgical pathology report (de-identified scan), TCGA case TCGA-23-1111, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1111-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. OMENTUM (RESECTION):

- Metastatic high-grade serous papillary adenocarcinoma (more than 2 cm in greatest dimension)

B. RIGHT COLON [MESENTERIC] TUMOR (EXCISION):

- Metastatic high-grade serous papillary adenocarcinoma

C. LEFT FALLOPIAN TUBE (SALPINGECTOMY):

- Left fallopian tube with:
- Microscopic foci of serosal involvement by high-grade serous papillary adenocarcinoma
- Free-floating clusters of tumor cells in fallopian tube lumen

D. RIGHT FALLOPIAN TUBE AND OVARY (SALPINGO-OOPHORECTOMY):

- Right ovary with high-grade serous papillary adenocarcinoma
- Tumor size: 11.0 cm in greatest dimension
- Specimen integrity: intact
- Adenocarcinoma involves ovarian parenchyma with extension into paraovarian soft tissue and focal involvement of serosal surface
- Right fallopian tube with focal serosal involvement by adenocarcinoma

E. LEFT OVARY (OOPHORECTOMY):

- Left ovary with high-grade serous papillary adenocarcinoma
- Tumor size: 5.5 cm in greatest dimension
- Specimen integrity: intact
- Adenocarcinoma involves ovarian parenchyma and serosal surface with extension into paraovarian soft tissue

F. UTERUS (SUPRACERVICAL HYSTERECTOMY):

- Uterine serosal and parametrial involvement by high-grade serous papillary adenocarcinoma
- Invasion into outer myometrium
- Foci of parametrial and myometrial lymphovascular invasion
- Benign endometrial polyps
- Adjacent atrophic endometrium with cystic glands and lymphoid aggregates
- Focal adenomyosis

G. BLADDER PERITONEUM (EXCISION):

- Metastatic high-grade serous papillary adenocarcinoma
-
-
-

[page 2 of 5]
PATIENT: [REDACTED]

PATH #: [REDACTED]

H. SIGMOID [MESENTERIC] TUMOR (EXCISION):

- Metastatic high-grade serous papillary adenocarcinoma

I. FALCIFORM LIGAMENT (EXCISION):

- Fatty and fibromuscular tissue with no evidence of malignancy

J. DIAPHRAGM TUMOR (EXCISION):

- Metastatic high-grade serous papillary adenocarcinoma

K. SUPRAGASTRIC TUMOR (EXCISION):

- Metastatic high-grade serous papillary adenocarcinoma
- One lymph node positive for metastatic adenocarcinoma (1/1)

COMMENT: Staging information (AJCC 2002): pT3c N1 Mx (corresponding FIGO stage IIIC). The adenocarcinoma shows serous features with a predominantly papillary architecture, associated psammoma bodies, and focal necrosis. Focal areas exhibit a hobnail pattern and cytoplasmic clearing suggesting the possibility of a minor clear cell component.

HISTORY: None given

MICROSCOPIC:

See diagnosis.

GROSS:

A. OMENTUM TUMOR

Labeled with the patient's name, labeled "omentum tumor", and received fresh for intraoperative frozen section consultation and subsequently fixed in formalin is a 13.0 x 10.0 x 4.0 cm aggregate of yellow fatty and tan firm tissue. Within the omentum are multiple tan firm nodules. The nodules are poorly circumscribed and infiltrating the fat.

Representative sections submitted.

A1. Remnant of FSA - 1

A2. Representative section of nodules - 1

B. RIGHT COLON TUMOR

Labeled with the patient's name, labeled "right colon tumor", and received in formalin is a 1.9 x 1.8 x 1.2 cm portion of tan tissue with a 1.9 x 1.4 cm tan firm nodule.

Entirely submitted.

B1. 2

B2. 3

C. LEFT FALLOPIAN TUBE

Labeled with the patient's name, labeled "left fallopian tube", and received in formalin is a fallopian tube measuring 5.5 cm in length and 0.5 cm in diameter with attached fimbria. No gross lesions are identified.

Representative sections submitted.

C1. Proximal, mid and distal fallopian tube and fimbria - 4

D. RIGHT TUBE AND OVARY

Labeled with the patient's name, labeled "right tube and ovary", and received fresh for intraoperative frozen section consultation is a 75.6 gram salpingo-oophorectomy specimen. The ovary measures 11.0 x 6.0 x 3.0 cm. The fallopian tube with fimbria measures 8.5 cm in length x 0.7 cm in diameter.

[page 3 of 5]
PATIENT: [REDACTED]

PATH #: [REDACTED]

The ovary is completely replaced by a cystic and solid neoplasm that involves the entire ovary. The serosa shows no gross tumor nodules and is pink-tan and smooth. The cystic component of the neoplasm accounts for 5% of the total volume, the solid component of the neoplasm accounts for 95% of the total volume. The cystic component is lined by papillary neoplasm that extends into the cystic cavity. The fallopian tube appears to be grossly uninvolved by tumor.

Representative sections submitted.

Slide key:

- D1. Remnant of FSD - 1
- D2. Representative sections of cyst wall - 3
- D3-D11. Representative section of papillary lesion - 1 each
- D12. Proximal, mid, distal fallopian tube and fimbria - 4

E. LEFT OVARY

Labeled with the patient's name, labeled "left ovary", and received fresh for intraoperative frozen section consultation and subsequently fixed in formalin is a 39 gram oophorectomy specimen without fallopian tube. The ovary measures 5.5 x 5.3 x 5.0 cm. The ovary is completely replaced by a solid neoplasm which shows papillated features with underlying tan firm nodular areas with focal yellowing of the nodules. The nodules range in size from 0.8 to 1.1 cm in greatest dimension. The serosal surface shows involvement by tumor.

Representative sections submitted.

- E1. Remnant of FSE - 1
- E2-E6. Representative sections of tumor - 1 each

F. SUPRACERVICAL UTERUS

Labeled with the patient's name, labeled "supracervical uterus", and received in formalin is a 98 gram previously opened supracervical uterus without attached fallopian tubes or ovaries. The uterus measures 5.0 x 4.5 x 2.8 cm. The endometrial cavity measures 4.4 cm in length and up to 3.2 cm in width.

The posterior endometrium displays three polypoid lesions measuring from 0.6 to 1.5 cm in greatest dimension. Sectioning reveals smooth polyps in the left anterior and posterior fundic region, measuring up to 1.5 cm in greatest dimension. The serosa displays papillated areas on the left posterior surface and bilateral parametria.

The myometrium measures 2.5 cm in thickness without lesion identified. The non-polypoid endometrium is tan, focally hemorrhagic.

Ink key:

- Anterior serosa - black
- Posterior serosa - blue
- Cervical resection margin - green

Slide key:

- F1. Anterior lower uterine segment margin - 1
- F2. Posterior lower uterine segment margin - 1
- F3. Anterior endometrium to serosa - 1
- F4. Posterior endometrium with polyp #1 - 1
- F5. Posterior endometrium with polyp #2 - 1
- F6. Posterior endometrium with polyp #3 - 1
- F7-F9. Representative sections of papillated lesion on left serosa/parametrium - 1 each
- F10. Right parametrium - 1

G. BLADDER PERITONEUM

[page 4 of 5]
PATIENT: [REDACTED]

PATH #: [REDACTED]

Labeled with the patient's name, labeled "bladder peritoneum", and received in formalin are two portions of yellow fatty tissue with a brown-tan granular peritoneal covering, with focal fibrinous material. The portions of tissue measure 2.6 x 1.5 x 0.5 cm and 4.5 x 2.0 x 0.7 cm. Representative sections submitted.

G1. 3

G2. 3

H. SIGMOID TUMOR

Labeled with the patient's name, labeled "sigmoid tumor", and received in formalin is a 6.0 x 1.7 x 1.0 cm portion of tan tissue with a tan firm nodule measuring approximately 1.4 cm in greatest dimension.

Representative sections are submitted.

H1. 2

H2. 4

I. FALCIFORM LIGAMENT

Labeled with the patient's name, labeled "falciform ligament", and received in formalin is a 9.0 x 6.0 x 1.5 cm portion of yellow fatty tissue with a portion of brown-tan peritoneal-covering. A tan nodule is identified measuring approximately 2.0 cm in greatest dimension. The area of firmness is entirely submitted.

I1. Tan lesion - 2

J. DIAPHRAGM TUMOR

Labeled with the patient's name, labeled "diaphragm tumor", and received in formalin is a 5.0 x 4.0 x 1.5 cm aggregate of a tan firm papillary tumor.

Representative sections are submitted.

J1-J3. Representative sections - 2 each

K. SUPRAGASTRIC TUMOR

Labeled with the patient's name, labeled "supragastric tumor", and received in formalin is a 2.7 x 2.0 x 1.5 cm portion of yellow fatty and tan tissue with focal papillated areas. Entirely submitted.

K1-K3. Representative sections - 2 each

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

SPECIMEN A: [REDACTED]

-

-

SPECIMEN B: FSB RIGHT TUBE AND OVARY (RECEIVED PREVIOUSLY OPENED):

-

Carcinoma

[page 5 of 5]
PATIENT:

PATH #:

Source: NCI Genomic Data Commons file ac08bdc3-a350-4c25-8ec3-beafa6900fc7 (TCGA-23-1111.BA3AE03C-74D4-4B5F-849F-71466BAE7C0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).